Gene-level copy-number profile of tumor specimen TCGA-FG-A70Y-01A from TCGA case TCGA-FG-A70Y, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 20.3 years (7,421 days).
Specimen TCGA-FG-A70Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.24812c32-cef1-4ff8-8995-af04625055c8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FG-A70Y-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bc883004-b404-4340-958b-d3f275017b0b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,220; copy number 2: 57,077; copy number 3: 507; copy number 4: 628; copy number 5: 339; copy number 6: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FG-A70Y-01A-12D-A34I-01): tumor purity 0.65, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 388 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:115,408,496–134,979,279, 277 genes, copy number 5 (broad region; genes not listed).
- chr10:44,712–3,816,169, 62 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:6,618,716–10,462,361, 49 genes, copy number 6: LINC02648, AL158210.1, LINP1, AL392086.2, LINC00706, LINC00707, AL392086.1, AL392086.3, LINC02665, AL590095.1, SFMBT2, COX6CP17, AL139125.1, LINC02642, RNU6-535P, AL445070.1, ITIH5, ITIH2, KIN, ATP5F1C, TAF3, AL353754.1, GATA3, GATA3-AS1, AL390294.1, PRPF38AP1, LINC00708, AL390835.1, AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3.

Autosomal genes at a single copy (total copy number 1): 1,220. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
